Somatic mutation profile of tumor specimen TCGA-B0-5692-01A (aliquot TCGA-B0-5692-01A-11D-1534-10) from TCGA case TCGA-B0-5692, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 66.1 years (24,140 days).
Specimen TCGA-B0-5692-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e67ea64c-7559-43f0-96a6-b25b2c64cf00.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-5692-11A (Solid Tissue Normal), aliquot TCGA-B0-5692-11A-01D-1534-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/060b6ae0-0e59-4a6c-abe8-b833991109d4

The open-access MAF lists 69 somatic variants for this specimen: 50 protein-altering or splice-affecting, 16 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 16, Frame Shift Del 8, Nonsense Mutation 5, In Frame Del 3, Frame Shift Ins 2, Splice Region 2, RNA 1, 3'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AADACL4 | c.1220T>C p.I407T | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as rs771149164, COSV66106095; called by mutect2, varscan2
- ACTR6 | c.1112A>G p.D371G | Missense Mutation (SNP) | VAF 218/713 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as COSV51841573; called by muse, mutect2, varscan2
- ADAMTS7 | c.2795C>T p.T932I | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as COSV66306732; called by muse, mutect2, varscan2
- ADGRA2 | c.2014C>G p.R672G | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV59442621; called by muse, mutect2, varscan2
- AMACR | c.826G>A p.A276T | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.104); catalogued as COSV56871094; called by muse, mutect2, varscan2
- AP1G2 | c.1019A>G p.D340G | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.882); catalogued as COSV55337905; called by muse, mutect2, varscan2
- CAP2 | c.1353A>G p.R451= | Splice Region (SNP) | VAF 159/639 reads (25%) | catalogued as COSV57731298; called by muse, mutect2, varscan2
- CCNB2 | c.1084A>T p.I362F | Missense Mutation (SNP) | VAF 72/262 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.167); catalogued as COSV55595264; called by muse, mutect2, varscan2
- CDH1 | c.944A>G p.N315S | Missense Mutation (SNP) | VAF 45/213 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV55730842, COSV55742342; called by muse, mutect2, varscan2
- CEP152 | c.670_672del p.Q224del | In Frame Del (DEL) | VAF 114/497 reads (23%) | catalogued as rs764982977; called by pindel, varscan2
- CHODL | c.312G>A p.W104* | Nonsense Mutation (SNP) | VAF 92/323 reads (28%) | catalogued as COSV54732165; called by muse, mutect2, varscan2
- COL11A1 | c.4438G>A p.G1480R | Missense Mutation (SNP) | VAF 59/201 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62180027; called by muse, mutect2, varscan2
- CXorf66 | c.629C>A p.P210H | Missense Mutation (SNP) | VAF 93/251 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.906); catalogued as rs760780875, COSV65169116; called by muse, mutect2, varscan2
- FAM76A | c.628C>A p.P210T | Missense Mutation (SNP) | VAF 63/244 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.053); catalogued as COSV50548924; called by muse, mutect2, varscan2
- GRIK3 | c.2115G>T p.E705D | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV66138221; called by muse, mutect2, varscan2
- GRIN2B | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV74205531; called by muse, mutect2, varscan2
- GSTA3 | c.370A>C p.I124L | Missense Mutation (SNP) | VAF 131/481 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.092); catalogued as COSV52980331; called by muse, mutect2, varscan2
- ITGB6 | c.1126G>C p.E376Q | Missense Mutation (SNP) | VAF 77/336 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.91); catalogued as COSV51792722; called by muse, mutect2, varscan2
- LARP1B | c.2473A>G p.K825E | Missense Mutation (SNP) | VAF 96/370 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs777794190, COSV52796352; called by muse, mutect2, varscan2
- MARCHF5 | c.609T>G p.H203Q | Missense Mutation (SNP) | VAF 106/399 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.01); catalogued as COSV62769494; called by muse, mutect2, varscan2
- MNDA | c.188A>G p.D63G | Missense Mutation (SNP) | VAF 63/426 reads (15%) | SIFT tolerated (0.77); PolyPhen benign (0.028); catalogued as COSV63740502, COSV63740869; called by muse, mutect2, varscan2
- MRTFB | c.219A>G p.P73= | Splice Region (SNP) | VAF 64/310 reads (21%) | catalogued as COSV57957254; called by muse, varscan2
- MYO1B | c.953C>A p.S318* | Nonsense Mutation (SNP) | VAF 71/354 reads (20%) | catalogued as COSV58429753; called by muse, mutect2, varscan2
- MYOM2 | c.493G>A p.V165I | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.076); catalogued as rs200247570, COSV50707935; called by muse, mutect2, varscan2
- PTCHD3 | c.997C>A p.P333T | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0.138); catalogued as COSV71256324, COSV71256659; called by muse, mutect2, varscan2
- PTP4A2 | c.243G>A p.W81* | Nonsense Mutation (SNP) | VAF 93/332 reads (28%) | catalogued as COSV59773780; called by muse, mutect2, varscan2
- RETSAT | c.374G>T p.R125L | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.258); catalogued as rs370464576, COSV55525646; called by muse, mutect2, varscan2
- RIMS2 | c.2182T>C p.S728P (on ENST00000666250 / NM_001348490.2; = p.S536P on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 108/420 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV51671393; called by muse, mutect2, varscan2
- RLF | c.547G>A p.V183M | Missense Mutation (SNP) | VAF 94/412 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs998584268, COSV65651436; called by muse, mutect2, varscan2
- RMDN3 | c.88C>A p.L30I | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0.006); catalogued as COSV53023710; called by muse, mutect2, varscan2
- SMC1B | c.1969A>C p.S657R | Missense Mutation (SNP) | VAF 257/944 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.78); catalogued as COSV62528259, COSV62529435; called by muse, mutect2, varscan2
- SPATA31D1 | c.4027C>T p.Q1343* | Nonsense Mutation (SNP) | VAF 16/54 reads (30%) | catalogued as COSV61194656; called by muse, mutect2, varscan2
- SYTL2 | c.1522C>T p.P508S | Missense Mutation (SNP) | VAF 90/339 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.406); catalogued as COSV60357951; called by muse, mutect2, varscan2
- VHL | c.522_523dup p.Y175Ffs*28 | Frame Shift Ins (INS) | VAF 52/140 reads (37%) | catalogued as COSV56571307; called by mutect2, pindel, varscan2
- WDFY3 | c.5719A>G p.I1907V | Missense Mutation (SNP) | VAF 71/254 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV55698546; called by muse, mutect2, varscan2
- ZBTB39 | c.1841T>C p.F614S | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55628980; called by muse, mutect2, varscan2
- ZFC3H1 | c.2925A>T p.E975D | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV66431711; called by muse, mutect2, varscan2
- ZMYND10 | c.1309G>T p.D437Y | Missense Mutation (SNP) | VAF 60/155 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs754752793, COSV51601207, COSV51602479; called by muse, mutect2, varscan2
- ABCB5 | c.904_906delinsAA p.Y302Kfs*11 | Frame Shift Del (DEL) | VAF 87/630 reads (14%) | called by pindel, varscan2*
- ACSL6 | c.816del p.I272Mfs*30 (on ENST00000379240; = p.I297Mfs*30 on NM_015256.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 42/194 reads (22%) | called by mutect2, pindel, varscan2
- ARID1A | c.1661del p.P554Hfs*65 | Frame Shift Del (DEL) | VAF 54/167 reads (32%) | called by mutect2, pindel, varscan2
- ATF4 | c.359_361del p.C120_D121delinsY | In Frame Del (DEL) | VAF 73/253 reads (29%) | called by mutect2, pindel, varscan2
- FAM217A | c.1399_1410del p.G467_K470del | In Frame Del (DEL) | VAF 48/239 reads (20%) | called by mutect2, pindel, varscan2
- FBN3 | c.3293_3294del p.C1098Sfs*5 | Frame Shift Del (DEL) | VAF 24/102 reads (24%) | called by pindel, varscan2
- LDB1 | c.207_208del p.Y69* (on ENST00000425280 / NM_001321612.2; = p.Y33* on NM_003893.5) | Nonsense Mutation (DEL) | VAF 148/597 reads (25%) | called by mutect2, pindel, varscan2
- NEK1 | c.3688del p.I1230Ffs*16 | Frame Shift Del (DEL) | VAF 69/275 reads (25%) | called by mutect2, pindel, varscan2
- SLC2A14 | c.690_696del p.E231Pfs*34 | Frame Shift Del (DEL) | VAF 60/304 reads (20%) | called by mutect2, pindel, varscan2
- TRAF3IP2 | c.521dup p.N174Kfs*10 | Frame Shift Ins (INS) | VAF 8/22 reads (36%) | called by mutect2, varscan2
- TRMT9B | c.175_178del p.L59Kfs*2 | Frame Shift Del (DEL) | VAF 47/247 reads (19%) | called by mutect2, pindel, varscan2
- YLPM1 | c.530del p.P177Rfs*42 | Frame Shift Del (DEL) | VAF 36/102 reads (35%) | called by mutect2, pindel, varscan2
- ANKS3 | c.366C>G p.L122= | Silent (SNP) | VAF 32/71 reads (45%) | catalogued as rs1374611348, COSV58508568; called by muse, mutect2, varscan2
- ARHGAP25 | c.654G>A p.G218= (on ENST00000409202 / NM_001007231.3; = p.G210= on NM_014882.3) | Silent (SNP) | VAF 28/102 reads (27%) | catalogued as rs1183028098, COSV54901156; called by muse, mutect2, varscan2
- COL1A1 | c.2892T>C p.P964= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as rs753585193, COSV56803801; called by muse, mutect2, varscan2
- CRHR2 | c.735C>A p.G245= | Silent (SNP) | VAF 115/371 reads (31%) | catalogued as COSV59264653; called by muse, mutect2, varscan2
- DAB2 | c.2013A>T p.G671= | Silent (SNP) | VAF 39/155 reads (25%) | catalogued as COSV57913740; called by muse, mutect2, varscan2
- FGF17 | c.219C>A p.I73= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV63925494; called by muse, mutect2, varscan2
- FIBP | c.504G>A p.R168= | Silent (SNP) | VAF 57/177 reads (32%) | catalogued as rs1254554715, COSV57033579; called by muse, mutect2, varscan2
- GJB4 | c.678C>T p.C226= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as COSV58355945; called by muse, mutect2, varscan2
- MYH13 | c.1125G>A p.A375= | Silent (SNP) | VAF 72/175 reads (41%) | catalogued as rs764762691, COSV52824039, COSV99355704; called by muse, mutect2, varscan2
- PIP4K2B | c.169C>T p.L57= | Silent (SNP) | VAF 99/337 reads (29%) | called by muse, mutect2, varscan2
- PPP4R1 | c.1542A>T p.L514= (on ENST00000400556 / NM_001042388.3; = p.L497= on NM_005134.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 85/351 reads (24%) | catalogued as COSV53281345; called by muse, mutect2, varscan2
- PSD2 | c.1746G>A p.R582= | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as COSV51198716; called by muse, mutect2, varscan2
- RASGRF1 | c.3708C>T p.Y1236= | Silent (SNP) | VAF 157/576 reads (27%) | catalogued as COSV67249777; called by muse, mutect2, varscan2
- RBM17 | c.210C>T p.D70= | Silent (SNP) | VAF 35/106 reads (33%) | catalogued as COSV65913823; called by muse, mutect2, varscan2
- SCUBE3 | c.2361C>T p.S787= | Silent (SNP) | VAF 35/144 reads (24%) | catalogued as COSV51456212; called by muse, mutect2, varscan2
- ZNF8 | c.528C>G p.L176= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as COSV52187278; called by muse, mutect2, varscan2
- ALKBH6 | c.-6G>A | 5'UTR (SNP) | VAF 43/186 reads (23%) | catalogued as COSV53324432; called by muse, mutect2, varscan2
- N4BP2L2 | chr13:32442465 C>G | 3'Flank (SNP) | VAF 76/221 reads (34%) | catalogued as COSV100679380, COSV62632383; called by muse, mutect2, varscan2
- SSPOP | n.3913G>A | RNA (SNP) | VAF 24/83 reads (29%) | catalogued as COSV50487125; called by muse, mutect2, varscan2
